Gene-level copy-number profile of tumor specimen HCM-WCMC-1074-C56-01A from HCMI case HCM-WCMC-1074-C56, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Mucinous adenocarcinoma; Tissue or organ of origin: Ovary; FIGO stage: Stage IC2; Age at diagnosis: 72.9 years (26,625 days).
Specimen HCM-WCMC-1074-C56-01A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file e3a0883c-d582-43e8-a09b-8d8b057284ee.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-WCMC-1074-C56-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,230 have no estimate.
https://portal.gdc.cancer.gov/files/8919b46d-d5bf-4e19-9976-7baf8af15256

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 1,104; copy number 1: 7,643; copy number 2: 46,508; copy number 3: 2,902; copy number 4: 150; copy number 5: 80; copy number 9: 1; copy number 10: 2; copy number 17: 3.

Homozygous deletions (total copy number 0; autosomes only): 1,104 genes in 36 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:12,938,472–13,032,130, 2 genes (within-gene range 0–2): PRAMEF6, PRAMEF28P.
- chr1:13,060,869–13,062,229, 1 gene (within-gene range 0–1): HNRNPCL3.
- chr1:13,172,455–13,226,106, 3 genes: PRAMEF9, PRAMEF13, PRAMEF18.
- chr1:13,279,125–13,421,328, 9 genes: RNU6-771P, PRAMEF8, PRAMEF33, PRAMEF15, AC243961.1, PRAMEF14, PRAMEF19, PRAMEF17, PRAMEF20.
- chr2:88,383,494–88,452,693, 4 genes: RNU6-1168P, RNU6-1007P, RPL38P6, FOXI3.
- chr3:50,876,712–50,877,657, 1 gene (within-gene range 0–1): ST13P14.
- chr3:109,176,438–109,216,965, 2 genes: AC063923.2, LINC00488.
- chr3:109,293,788–109,723,273, 8 genes (within-gene range 0–2): DPPA2, Metazoa_SRP, DPPA4, AC124945.1, AC092905.1, H3P12, LINC01205, PPIAP15.
- chr4:8,846,076–8,871,839, 2 genes: HMX1, AC116612.1.
- chr4:25,622,777–25,623,601, 1 gene: AC092436.1.
- chr7:56,805,336–56,944,353, 4 genes: CICP28, AC118758.2, AC118758.1, AC069152.1.
- chr7:152,445,477–152,465,549, 2 genes: CCT8L1P, LINC01003.
- chr8:33,715,784–33,723,079, 2 genes (within-gene range 0–2): RN7SL457P, VENTXP5.
- chr9:12,134–1,978,547, 33 genes: DDX11L5, WASHC1, MIR1302-9HG, MIR1302-9, FAM138C, AL449043.2, PGM5P3-AS1, AL449043.1, LINC01388, FOXD4, CBWD1, DOCK8-AS1, DOCK8, AL158832.1, AL161725.1, KANK1, RPL12P25, AL161725.2, AL392089.1, RNU6-1327P, EIF1P1, AL136979.1, DMRT1, DMRT3, RNU6-1073P, H3P29, LINC01230, DMRT2, AL356498.1, RPS27AP14, AL358934.1, RNA5SP279, AL591644.1.
- chr9:21,695,176–23,956,444, 30 genes: KHSRPP1, RN7SL151P, MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2, AL157937.1, DMRTA1, LINC01239, AL391117.1, CLIC4P1, AC017067.1, AL445623.2, SUMO2P2, AL445623.1, NOP56P2, ELAVL2, AL365204.1, AL365204.2, AL365204.3.
- chr9:61,665,579–61,789,426, 2 genes: AL935212.2, RN7SL722P.
- chr9:61,861,625–61,911,022, 6 genes: AL391987.2, AL391987.1, AL391987.4, AL391987.3, Y_RNA, FAM242E.
- chr9:63,703,065–63,762,824, 5 genes: AL591438.2, CDRT15P7, AL772155.1, AL772155.2, MYO5BP3.
- chr10:16,276,871–16,295,858, 1 gene: LINC02654.
- chr10:37,775,371–37,994,975, 11 genes: AL132657.1, ZNF248, AL132657.2, ZNF33BP1, TLK2P2, AL135791.1, ZNF37CP, ZNF33CP, ZNF25, ZNF25-DT, Y_RNA.
- chr11:7,745,990–7,746,906, 1 gene (within-gene range 0–2): OR5P4P.
- chr12:114,408,173–114,412,831, 1 gene (within-gene range 0–2): TBX5-AS1.
- chr14:78,059,942–78,060,278, 1 gene: FXNP1.
- chr16:29,380,242–29,380,345, 1 gene: AC025279.3.
- chr16:29,475,064–29,505,999, 3 genes: AC133555.2, AC133555.1, NPIPB12.
- chr16:54,239,693–54,292,422, 5 genes: AC007907.1, LINC02169, IRX3, AC018553.2, AC018553.1.
- chr17:6,163,893–6,207,269, 2 genes: AC104770.1, RNU6-1264P.
- chr17:20,771,058–20,771,427, 1 gene: HNRNPA1P19.
- chr17:22,298,691–22,332,410, 2 genes: FAM27E5, AC087575.1.
- chr19:5,993,164–6,199,572, 1 gene (within-gene range 0–2): RFX2.
- chr19:6,109,322–18,285,495, 683 genes (broad region; genes not listed).
- chr19:18,571,730–24,163,425, 258 genes (broad region; genes not listed).
- chr19:54,890,673–54,966,312, 4 genes (within-gene range 0–2): AC245128.3, NCR1, NLRP7, AC011476.8.
- chr20:21,947,647–22,074,654, 2 genes: AL109807.1, LINC01432.
- chr20:56,577,563–56,731,460, 7 genes: LINC01716, RPS4XP3, TFAP2C, RNU6-1146P, RN7SL170P, PTMAP6, AL133232.1.
- chr21:44,285,838–44,330,221, 3 genes (within-gene range 0–2): AIRE, PFKL, AP001062.3.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 86 genes in 16 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:207,018,522–207,099,993, 4 genes, copy number 5: C1orf116, PFKFB2, YOD1, C4BPB.
- chr3:14,112,077–14,148,252, 3 genes, copy number 5 (within-gene range 4–5): CHCHD4, TMEM43, AC090004.1.
- chr6:11,183,298–11,515,710, 4 genes, copy number 5 (within-gene range 2–5): NEDD9, AL022098.1, AL445430.2, AL445430.1.
- chr6:43,995,723–44,089,288, 3 genes, copy number 5 (within-gene range 3–5): AL109615.3, C6orf223, AL109615.2.
- chr9:94,726,604–95,087,159, 7 genes, copy number 5 (within-gene range 2–5): AOPEP, MIR2278, AL807757.1, AL807757.2, AL353768.1, AL353768.2, MIR6081.
- chr10:88,879,734–88,991,339, 3 genes, copy number 5 (within-gene range 2–5): STAMBPL1, ACTA2-AS1, ACTA2.
- chr14:67,819,779–68,730,218, 1 gene, copy number 5 (within-gene range 3–5): RAD51B.
- chr14:68,149,617–68,628,445, 6 genes, copy number 5: RN7SL706P, RN7SL108P, AL122013.1, PPIAP6, AL121820.3, AL121820.2.
- chr14:68,693,656–68,695,734, 1 gene, copy number 5: AL133313.1.
- chr17:50,055,968–50,287,855, 18 genes, copy number 5: ITGA3, AC002401.4, PDK2, AC002401.3, AC002401.2, SAMD14, PPP1R9B, AC002401.1, AC015909.2, AC015909.3, SGCA, H1-9P, COL1A1, AC015909.1, AC015909.4, SUMO2P7, TMEM92, TMEM92-AS1.
- chr17:50,634,777–50,756,219, 6 genes, copy number 5: ABCC3, ANKRD40, AC005921.2, Y_RNA, LUC7L3, AC005921.3.
- chr17:78,852,977–78,925,387, 1 gene, copy number 5 (within-gene range 4–5): TIMP2.
- chr17:78,870,910–79,027,673, 6 genes, copy number 5 (within-gene range 1–5): CEP295NL, AC100788.2, AC100788.1, LGALS3BP, CANT1, C1QTNF1-AS1.
- chr19:41,652,676–41,811,554, 7 genes, copy number 5: AC243960.4, CEACAM7, CEACAM5, AC243967.1, CEACAM6, AC243967.2, CEACAM3.
- chr19:45,379,638–45,602,212, 10 genes, copy number 5 (within-gene range 3–5): PPP1R13L, POLR1G, ERCC1, MIR6088, FOSB, RTN2, PPM1N, VASP, OPA3, GPR4.
- chr21:44,200,602–44,262,216, 6 genes, copy number 9–17 (within-gene range 8–17): AP001057.1, ICOSLG, AP001059.2, AP001059.1, DNMT3L, DNMT3L-AS1.

Autosomal genes at a single copy (total copy number 1): 5,305. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
